Somatic mutation profile of tumor specimen TCGA-26-5136-01B (aliquot TCGA-26-5136-01B-01D-1486-08) from TCGA case TCGA-26-5136, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.0 years (28,496 days).
Specimen TCGA-26-5136-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1879062d-e922-4f6a-a959-f839f9869909.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-5136-10A (Blood Derived Normal), aliquot TCGA-26-5136-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2cc4832-6263-490b-bb5a-43db4ef13eac

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 13, Nonsense Mutation 3, Splice Site 3, RNA 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 17/237 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55897314, COSV55951959; called by muse, mutect2
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 58/74 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs767886701, COSV62415102; called by muse, mutect2, varscan2
- ATP2B3 | c.3263A>T p.E1088V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV54853690; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 127/460 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140138864; called by muse, mutect2, varscan2
- CDH15 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157893740, COSV57025667; called by muse, mutect2, varscan2
- CDH5 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs376317308, COSV58518605; called by muse, mutect2, varscan2
- COL6A3 | c.6064-1G>C p.X2022_splice | Splice Site (SNP) | VAF 72/198 reads (36%) | catalogued as COSV55097708; called by muse, mutect2, varscan2
- DMBT1 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 177/262 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs199833346; called by muse, mutect2, varscan2
- EPC1 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV53927609; called by muse, mutect2, varscan2
- HSP90AB1 | c.354+1G>T p.X118_splice | Splice Site (SNP) | VAF 85/223 reads (38%) | catalogued as COSV62335509; called by muse, mutect2, varscan2
- MAST3 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 97/168 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1423581567, COSV53223171; called by muse, mutect2
- MSL3 | c.1282-1G>A p.X428_splice (on ENST00000312196 / NM_078629.4; = p.X262_splice on NM_006800.4) | Splice Site (SNP) | VAF 204/511 reads (40%) | catalogued as COSV56494586; called by muse, mutect2, varscan2
- MYCN | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55257982, COSV99808532; called by muse, mutect2, varscan2
- NECTIN4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV63513289; called by muse, mutect2, varscan2
- NWD1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 75/113 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs753810178, COSV60346078; called by muse, mutect2, varscan2
- OR2F2 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 208/694 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101283806, COSV68833035; called by muse, mutect2, varscan2
- OR2T6 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1457124518, COSV63216707; called by muse, mutect2
- OXSM | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs370766105; called by muse, mutect2, varscan2
- PARP12 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs764607102, COSV54935667; called by muse, mutect2, varscan2
- PHF12 | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV52020534; called by muse, mutect2, varscan2
- PRKX | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53325126; called by muse, mutect2, varscan2
- RADX | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV65319316; called by muse, mutect2, varscan2
- SAMHD1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53430834; called by muse, mutect2, varscan2
- SCN9A | c.1754G>C p.R585T | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV57615918; called by muse, varscan2
- SIPA1L2 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 84/221 reads (38%) | catalogued as COSV53383810; called by muse, mutect2, varscan2
- SLC4A2 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); catalogued as rs747989506, COSV52529975, COSV52531491; called by muse, mutect2, varscan2
- TBC1D12 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV56555735; called by muse, mutect2, varscan2
- TMEM164 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 66/183 reads (36%) | catalogued as COSV55813811; called by muse, mutect2, varscan2
- TREX2 | c.418G>A p.V140M (on ENST00000334497; = p.V97M on NM_080701.3) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs782119886, COSV57847763; called by muse, mutect2, varscan2
- TRIM49 | c.1190T>A p.L397H | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61671311; called by muse, mutect2, varscan2
- TRIM50 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 118/500 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as rs184647228, COSV60794385; called by muse, mutect2, varscan2
- XK | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66120472; called by muse, mutect2, varscan2
- ZNF644 | c.2518G>A p.V840I | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs267598765, COSV61347327; called by muse, mutect2, varscan2
- TIGD7 | c.1215_1227del p.K405Nfs*7 | Frame Shift Del (DEL) | VAF 119/474 reads (25%) | called by mutect2, pindel, varscan2
- TRDV1 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 108/353 reads (31%) | called by muse, mutect2, varscan2
- ANGPTL5 | c.927G>A p.G309= | Silent (SNP) | VAF 74/185 reads (40%) | catalogued as COSV57533735; called by muse, mutect2, varscan2
- EPB41L3 | c.2046G>A p.P682= | Silent (SNP) | VAF 50/226 reads (22%) | catalogued as rs549355143, COSV100550302, COSV59460167; called by muse, mutect2, varscan2
- FAM13A | c.396G>A p.A132= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs147082682; called by muse, mutect2, varscan2
- OTUD5 | c.537C>T p.D179= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs782248683, COSV50237361; called by muse, mutect2, varscan2
- PEAR1 | c.1491C>T p.A497= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV52774340; called by muse, mutect2, varscan2
- PEX11A | c.732G>A p.L244= | Silent (SNP) | VAF 239/627 reads (38%) | catalogued as COSV55584301; called by muse, mutect2, varscan2
- PIK3CD | c.1401C>T p.S467= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs200295565, COSV63130076; ClinVar: likely benign; called by muse, mutect2, varscan2
- RABGEF1 | c.744T>C p.D248= (on ENST00000439720 / NM_001287061.2; = p.D235= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 63/233 reads (27%) | catalogued as COSV53163422; called by muse, mutect2, varscan2
- SIPA1L2 | c.4545C>T p.N1515= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs370081594; called by muse, mutect2, varscan2
- TEX11 | c.1470C>T p.N490= (on ENST00000344304; = p.N475= on NM_031276.3) | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as rs1168415970, COSV60234072; called by muse, mutect2, varscan2
- TSPAN9 | c.408C>T p.N136= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs766796551, COSV50724342; called by muse, mutect2, varscan2
- UBA1 | c.2037G>C p.L679= | Silent (SNP) | VAF 90/254 reads (35%) | catalogued as COSV60113759; called by muse, mutect2, varscan2
- UGT2B10 | c.1482G>T p.G494= | Silent (SNP) | VAF 116/320 reads (36%) | catalogued as COSV55321816; called by muse, mutect2, varscan2
- ANKRD33 | c.664+93G>A | Intron (SNP) | VAF 28/85 reads (33%) | catalogued as COSV56608426; called by muse, mutect2, varscan2
- C9orf163 | n.1163G>A | RNA (SNP) | VAF 17/47 reads (36%) | catalogued as rs769178010; called by muse, mutect2, varscan2
